Somatic mutation profile of tumor specimen TARGET-10-PASYSJ-09A (aliquot TARGET-10-PASYSJ-09A-01D) from TARGET case TARGET-10-PASYSJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.7 years (5,379 days).
Specimen TARGET-10-PASYSJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8ec36d8-fe71-4c56-9f33-4d48b98b7aa6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASYSJ-10A (Blood Derived Normal), aliquot TARGET-10-PASYSJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/312c766e-cd02-45cc-a104-2ab1be695bff

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Nonsense Mutation 2, 3'Flank 2, In Frame Del 2, Splice Region 1, Intron 1, RNA 1, 3'UTR 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS3 | c.770A>T p.N257I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54393282; called by muse, mutect2, varscan2
- ARRDC2 | c.342-2A>G p.X114_splice | Splice Site (SNP) | VAF 10/73 reads (14%) | catalogued as rs868570374, COSV55844712; called by muse, mutect2, varscan2
- ATP9A | c.1065G>T p.K355N | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58767406; called by muse, mutect2, varscan2
- CTNND1 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV62383870; called by muse, mutect2, varscan2
- FUT4 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV62469444; called by muse, mutect2, varscan2
- GLS | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as rs16833035; called by mutect2, varscan2
- GTF2IRD1 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs150553675; called by muse, mutect2, varscan2
- HACD2 | c.431C>T p.T144M | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760461596, COSV67322750; called by muse, mutect2, varscan2
- KDM6A | c.3335_3336insGTTCACTC p.V1113Ffs*10 | Frame Shift Ins (INS) | VAF 10/13 reads (77%) | catalogued as COSV65038350, COSV65040955; called by mutect2, varscan2
- MICAL2 | c.4619G>A p.R1540Q | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.476); catalogued as rs745884670, COSV56284815; called by muse, mutect2, varscan2
- MYH6 | c.1426C>A p.Q476K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as COSV62451368; called by muse, mutect2, varscan2
- NOTCH1 | c.7507C>T p.Q2503* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as COSV53031077; called by muse, mutect2, varscan2
- NOTCH1 | c.7180C>T p.Q2394* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV53037277; called by muse, mutect2, varscan2
- PAMR1 | c.1732C>T p.P578S (on ENST00000619888 / NM_001001991.3; = p.P595S on NM_015430.4) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53513165; called by muse, mutect2, varscan2
- PCSK6 | c.2306G>A p.R769H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.912); catalogued as rs201737898; called by muse, mutect2, varscan2
- PRPF39 | c.1527_1535del p.P510_S512del | In Frame Del (DEL) | VAF 14/30 reads (47%) | catalogued as COSV53532635; called by mutect2, pindel, varscan2
- SCN11A | c.5275C>A p.Q1759K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs756161746, COSV56571484; called by muse, mutect2, varscan2
- SLC27A6 | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52483807; called by muse, mutect2, varscan2
- IZUMO1R | c.672_674del p.S225del (on ENST00000440961; = p.S232del on NM_001199206.3) | In Frame Del (DEL) | VAF 12/33 reads (36%) | called by pindel*, varscan2
- TRAJ11 | chr14:22532489 del ATTTGCTATAGTGTGA | Missense Mutation (DEL) | VAF 6/20 reads (30%) | called by pindel, varscan2
- TRIO | c.6465+3A>T | Splice Region (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- LAMB4 | c.2019C>A p.P673= | Silent (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- NAGK | c.330C>G p.G110= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- PRSS35 | c.1047G>A p.G349= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs963817861, COSV100864162; called by muse, mutect2, varscan2
- SALL4 | c.636G>A p.P212= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs750424449, COSV53851222; called by muse, mutect2, varscan2
- SIPA1 | c.1491C>T p.F497= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs1280356098; called by muse, mutect2, varscan2
- CARNS1 | chr11:67428485 G>A | 3'Flank (SNP) | VAF 6/16 reads (38%) | catalogued as rs529752764; called by muse, varscan2
- CD320 | c.*172C>T | 3'UTR (SNP) | VAF 13/28 reads (46%) | catalogued as rs760525156, COSV100035858; called by muse, mutect2, varscan2
- NPEPL1 | chr20:58717906 C>T | 3'Flank (SNP) | VAF 12/28 reads (43%) | catalogued as rs139663802; called by muse, mutect2, varscan2
- SLC2A8 | c.724-19C>A | Intron (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2
- SNORD115-44 | n.38G>A | RNA (SNP) | VAF 22/47 reads (47%) | catalogued as rs769254699; called by muse, mutect2, varscan2
